TCGA case TCGA-VS-A8QH — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Cervix uteri; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c4f61715-ee58-4799-a5f4-0f5e27c4093d

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 76 years; Vital status: Dead; Days to death: 1,210 days (3.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Mucinous adenocarcinoma, endocervical type: ICD-O-3 morphology code: 8482/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 76.4 years (27,909 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: MX; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 62 days; Days to treatment end: 98 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 62 days; Days to treatment end: 98 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 126 days; Days to treatment end: 161 days; Treatment dose: 4,500 cGy; Treatment outcome: Partial Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 164 days; Days to treatment end: 187 days; Treatment dose: 2,700 cGy; Treatment outcome: Partial Response; Number of fractions: 4; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 3; Treatment outcome: Partial Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Number of cycles: 3; Treatment outcome: Partial Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Treatment dose: 4,500 cGy; Treatment outcome: Partial Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.

Follow-up (2 entries)
- Day -1 (prior to adjuvant therapy): ECOG performance status: 0.
- Days to follow up: 1,210 days (3.3 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 159 cm; BMI: 28.9.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 3; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VS-A8QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 40 mg.
  Slide TCGA-VS-A8QH-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-VS-A8QH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VS-A8QH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 3; Pregnancies count miscarriage: 1; Total pregnancy count: 4; Tobacco smoking history indicator: 1; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Partial Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Mucinous Adenocarcinoma of Endocervical Type; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Cause of death: Cervical Cancer; New tumor event diagnosis indicator: No.
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: 3D conformal.
- Treatment, Concurrent prescription treatment info: Chemo concurrent reason not given: Adverse event/ complications.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment 1: Chemo concurrent fractions total: 3.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,210 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,210 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,210 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VS-A8QH-01A-11D-A37M-01): tumor purity 0.59, ploidy 1.93, whole-genome doublings 0.
